Gene-level copy-number profile of tumor specimen TCGA-ZX-AA5X-01A from TCGA case TCGA-ZX-AA5X, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 64.2 years (23,440 days).
Specimen TCGA-ZX-AA5X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.10796823-a1ca-480a-b99f-5f29e42432d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZX-AA5X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/353ac84a-416a-4d91-a1a3-e345780289ce

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 2: 3,577; copy number 3: 19; copy number 4: 49,754; copy number 5: 761; copy number 6: 5,101; copy number 8: 592.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZX-AA5X-01A-11D-A42N-01): tumor purity 0.37, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,857,270–233,586,291, 16 genes: SNORC, NGEF, AC106876.1, NEU2, INPP5D, RN7SL32P, ATG16L1, SCARNA5, SCARNA6, SAG, AC013726.1, DGKD, Y_RNA, USP40, PPFIA1P1, UGT1A12P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
